Surgical pathology report (de-identified scan), TCGA case TCGA-E8-A414, project TCGA-THCA (Thyroid Carcinoma), tissue source site Asterand, specimen TCGA-E8-A414-01A (Primary Tumor).

Procurement Date: Laterality: Tumor consists of papillae having an fine fibrovascular stalk covered by a single to mutiple layers of cuboidal epithelial cells. Tumor invades in capsule or vessle. The cells tend to maintain their polarity. Nuclei are quite regular and contain finely dispersed chromatin, or intranuclear grooves. Tumor is invasion of lymphocytes and fibrous.

Path Report: Tumor type: Papillary carcinoma

Tumor size: 5x3x3cm

Laterality: left

Tumor focality: Unifocal

Invasion of capsule: Yes

Extrathyroidal extension: No

1CD-0-3

carcinoma, papillary, thyroid

Site: thyroid, Nos 8260/3

C73.9 7-2012 EO

Source: NCI Genomic Data Commons file 02e0cdbe-a101-46e8-b21a-17611555edff (TCGA-E8-A414.ACDA1B0C-0F5D-40E3-936A-C96D921B861A.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).